Somatic mutation profile of tumor specimen TCGA-75-7027-01A (aliquot TCGA-75-7027-01A-11D-1945-08) from TCGA case TCGA-75-7027, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-75-7027-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abed1903-4541-4fa2-a274-079a88bee472.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-75-7027-10A (Blood Derived Normal), aliquot TCGA-75-7027-10A-01D-1946-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b931fc3c-3928-4737-8316-5832ec099b4f

The open-access MAF lists 259 somatic variants for this specimen: 186 protein-altering or splice-affecting, 70 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 162, Silent 70, Nonsense Mutation 10, Frame Shift Del 5, Splice Site 3, Frame Shift Ins 3, Splice Region 2, 5'UTR 2, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA2 | c.1018-1G>T p.X340_splice | Splice Site (SNP) | VAF 42/62 reads (68%) | catalogued as rs869320668, CS116981, CS116998, COSV100351472, COSV62007543; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 27/46 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50266507; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RHOA | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 126/224 reads (56%) | hotspot (GDC flag); catalogued as COSV69041613, COSV69042111, COSV69043712; called by muse, mutect2, varscan2
- AASS | c.583G>T p.V195L | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62791999; called by muse, mutect2, varscan2
- ABCA12 | c.7399T>A p.F2467I (on ENST00000272895 / NM_173076.3; = p.F2149I on NM_015657.3) | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV55976503; called by muse, mutect2, varscan2
- ABI3 | c.986T>A p.F329Y | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56801539; called by muse, mutect2, varscan2
- ACACB | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs747456016, COSV58147245; called by muse, mutect2, varscan2
- ACADM | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57714725; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2198C>T p.T733M | Missense Mutation (SNP) | VAF 73/122 reads (60%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.518); catalogued as rs1346418193; called by muse, mutect2, varscan2
- ADCY10 | c.1733C>T p.T578I | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.216); catalogued as COSV63245124; called by muse, mutect2, varscan2
- ADGRF4 | c.580C>A p.L194I | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51957776; called by muse, mutect2, varscan2
- AGO3 | c.705G>T p.M235I | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV55797407; called by muse, mutect2, varscan2
- AHNAK | c.9355G>A p.D3119N | Missense Mutation (SNP) | VAF 54/684 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV57231553; called by muse, mutect2
- AHNAK2 | c.11821C>T p.P3941S | Missense Mutation (SNP) | VAF 239/383 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV60931610; called by muse, mutect2, varscan2
- AIPL1 | c.166G>T p.G56C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100006213; called by mutect2, varscan2
- ALPK3 | c.3484G>C p.G1162R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51940229; called by muse, mutect2, varscan2
- ARAP2 | c.3217C>T p.Q1073* | Nonsense Mutation (SNP) | VAF 248/384 reads (65%) | catalogued as COSV58292774; called by muse, mutect2, varscan2
- ARL6 | c.413T>G p.V138G | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV60119049; called by muse, mutect2, varscan2
- ATG9B | c.701G>T p.R234L | Missense Mutation (SNP) | VAF 92/308 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.018); catalogued as COSV65059865; called by muse, mutect2, varscan2
- ATP8B4 | c.3302G>T p.R1101L | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV52724899; called by muse, mutect2
- ATP8B4 | c.3300C>T p.I1100= | Splice Region (SNP) | VAF 29/177 reads (16%) | catalogued as COSV52716104, COSV52724911; called by muse, mutect2
- BAIAP3 | c.1964C>T p.T655I | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs768687366, COSV50105597; called by muse, mutect2, varscan2
- BIRC7 | c.759G>T p.K253N (on ENST00000217169 / NM_139317.3; = p.K235N on NM_022161.4) | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53903390; called by muse, mutect2, varscan2
- CA1 | c.270G>C p.R90S | Missense Mutation (SNP) | VAF 71/187 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56280173; called by muse, mutect2, varscan2
- CAMKK2 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV61217960; called by muse, mutect2, varscan2
- CCDC88C | c.3437A>G p.K1146R | Missense Mutation (SNP) | VAF 71/110 reads (65%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as COSV66241945; called by muse, mutect2, varscan2
- CCNE2 | c.800A>T p.Y267F | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV57377572; called by muse, mutect2, varscan2
- CDH22 | c.1111G>T p.D371Y | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.933); catalogued as COSV64839753; called by muse, mutect2, varscan2
- CFAP251 | c.2027T>C p.L676P | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56616171; called by muse, mutect2, varscan2
- CFHR5 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV56820202; called by muse, mutect2, varscan2
- CHN1 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 112/205 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); catalogued as COSV55036158; called by muse, mutect2, varscan2
- CHST6 | c.605G>T p.R202L | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60001796; called by muse, mutect2, varscan2
- CLNK | c.696C>A p.N232K | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV57022586; called by muse, mutect2, varscan2
- CLOCK | c.352C>G p.L118V | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59405052; called by muse, mutect2, varscan2
- CLU | c.157G>T p.V53L | Missense Mutation (SNP) | VAF 79/248 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as COSV57068526; called by muse, mutect2, varscan2
- COL12A1 | c.7559G>T p.G2520V | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59408561; called by muse, mutect2, varscan2
- COL5A2 | c.2743G>T p.G915C | Missense Mutation (SNP) | VAF 87/233 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66415635; called by muse, mutect2, varscan2
- CPQ | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.114); catalogued as COSV55139966; called by muse, mutect2, varscan2
- CPS1 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149930500, CM114315, COSV51802056; called by muse, mutect2, varscan2
- CRACD | c.2971C>T p.R991C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV51732033; called by muse, mutect2, varscan2
- CRISPLD1 | c.296G>T p.W99L | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100082510, COSV51552889; called by muse, mutect2, varscan2
- CRISPLD1 | c.297G>T p.W99C | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51550574; called by muse, mutect2, varscan2
- CSMD3 | c.9503G>C p.C3168S (on ENST00000297405 / NM_001363185.1; = p.C2999S on NM_052900.3) | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV52122205, COSV52326890, COSV99851665; called by muse, mutect2, varscan2
- CSMD3 | c.2971C>G p.R991G (on ENST00000297405 / NM_001363185.1; = p.R887G on NM_052900.3) | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52182083, COSV52326902, COSV99828366; called by muse, mutect2, varscan2
- CTNND2 | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as rs376760091; called by muse, mutect2, varscan2
- CYLC1 | c.632C>A p.T211N | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.38); PolyPhen benign (0.043); catalogued as COSV61415015; called by muse, mutect2, varscan2
- DDX42 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 102/242 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63791489; called by muse, mutect2, varscan2
- DMXL1 | c.1738G>T p.G580C | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as COSV60721307; called by muse, mutect2, varscan2
- DNAJA3 | c.953T>A p.V318E | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52164298; called by muse, mutect2, varscan2
- DPEP2 | c.909+1G>T p.X303_splice | Splice Site (SNP) | VAF 191/395 reads (48%) | catalogued as COSV52056177; called by muse, mutect2, varscan2
- DSE | c.1876G>C p.E626Q | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.098); catalogued as COSV59067585; called by muse, mutect2, varscan2
- DSPP | c.1551C>G p.S517R | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.743); catalogued as COSV56816884; called by muse, mutect2, varscan2
- DUSP9 | c.1028G>C p.S343T | Missense Mutation (SNP) | VAF 153/198 reads (77%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV61438493; called by muse, mutect2, varscan2
- DYNC2I1 | c.2072A>C p.K691T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV68107379; called by muse, mutect2, varscan2
- EDIL3 | c.645G>T p.W215C | Missense Mutation (SNP) | VAF 80/131 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56917706, COSV56922430; called by muse, mutect2, varscan2
- EEF2K | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 30/187 reads (16%) | catalogued as rs148576611, COSV53787356; called by muse, mutect2, varscan2
- EGFL8 | c.742C>A p.Q248K | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT tolerated (0.85); PolyPhen benign (0.023); catalogued as COSV61248731; called by muse, varscan2
- EGFLAM | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59312729, COSV59318651; called by muse, mutect2, varscan2
- EGR1 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 90/141 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53521673, COSV53521819; called by muse, mutect2, varscan2
- ELN | c.253G>T p.V85F | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.189); catalogued as COSV52708017, COSV52716031; called by muse, mutect2, varscan2
- EN1 | c.907G>C p.D303H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54632649; called by muse, mutect2, varscan2
- ENTPD7 | c.545A>T p.E182V | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV65113315; called by muse, mutect2, varscan2
- FAM171A1 | c.1457G>T p.R486M | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65320343; called by muse, mutect2, varscan2
- FAM193A | c.629G>T p.R210I | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61199006; called by muse, mutect2, varscan2
- FAM47A | c.1699C>A p.H567N | Missense Mutation (SNP) | VAF 65/81 reads (80%) | SIFT tolerated (0.06); PolyPhen benign (0.35); catalogued as COSV60494310; called by muse, varscan2
- FAM83H | c.2866A>T p.S956C | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as rs1554621921, COSV62030370; called by muse, mutect2, varscan2
- FLG | c.6982G>A p.E2328K | Missense Mutation (SNP) | VAF 705/1638 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.129); catalogued as rs762998429, COSV64250003; called by muse, mutect2, varscan2
- FNIP2 | c.2250G>C p.E750D | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.037); catalogued as COSV52446217; called by muse, mutect2, varscan2
- FOXM1 | c.965A>T p.Q322L | Missense Mutation (SNP) | VAF 82/181 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61207637; called by muse, mutect2, varscan2
- GIMAP4 | c.358G>T p.V120L | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763091896, COSV55434829; called by muse, mutect2, varscan2
- GPR158 | c.2914A>T p.K972* | Nonsense Mutation (SNP) | VAF 43/201 reads (21%) | catalogued as rs1352121437, COSV66283199; called by muse, mutect2, varscan2
- GPR50 | c.1586C>A p.P529H | Missense Mutation (SNP) | VAF 126/161 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); catalogued as COSV54443059; called by muse, mutect2, varscan2
- GPRC6A | c.283C>A p.L95M | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59956154; called by muse, mutect2, varscan2
- HTR1E | c.911G>T p.W304L | Missense Mutation (SNP) | VAF 84/258 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59511232; called by muse, mutect2, varscan2
- HTRA4 | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56761289; called by muse, mutect2, varscan2
- IL37 | c.170C>A p.P57Q | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.578); catalogued as rs200591262, COSV54493204; called by mutect2, varscan2
- INO80 | c.1771C>G p.P591A | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62742896; called by muse, mutect2, varscan2
- IQGAP3 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 50/351 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs375168150; called by muse, mutect2, varscan2
- KCNK18 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 71/186 reads (38%) | catalogued as rs3026042, COSV57971014, COSV57973091, COSV57973363; called by muse, mutect2, varscan2
- KDM7A | c.583A>G p.I195V | Missense Mutation (SNP) | VAF 74/312 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); catalogued as COSV50096701; called by muse, mutect2, varscan2
- KHDRBS2 | c.284C>A p.T95K | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55493839; called by muse, mutect2, varscan2
- KIAA1109 | c.191A>G p.Y64C | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as COSV52666476, COSV52693835; called by muse, mutect2, varscan2
- KLKB1 | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.041); catalogued as rs750899027, COSV52999614; called by muse, mutect2, varscan2
- KMT2D | c.2179C>T p.P727S | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.103); catalogued as COSV56488909; called by muse, mutect2, varscan2
- KRT37 | c.995T>A p.V332E | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV56660116; called by muse, mutect2, varscan2
- KRT37 | c.144C>A p.N48K | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.048); catalogued as rs751933378, COSV56660125; called by muse, mutect2, varscan2
- LAMA4 | c.3514G>A p.D1172N (on ENST00000230538 / NM_001105206.3; = p.D1165N on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57895653, COSV57905490; called by muse, mutect2, varscan2
- LRRC30 | c.368T>A p.F123Y | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.32); catalogued as COSV67302367; called by muse, mutect2, varscan2
- LRRC4 | c.152C>A p.S51* | Nonsense Mutation (SNP) | VAF 87/184 reads (47%) | catalogued as COSV50818991; called by muse, mutect2, varscan2
- LRRC7 | c.4201G>A p.D1401N (on ENST00000651989 / NM_001370785.2; = p.D1321N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/60 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV50635492; called by muse, mutect2, varscan2
- LRRIQ1 | c.982dup p.I328Nfs*38 | Frame Shift Ins (INS) | VAF 16/75 reads (21%) | catalogued as rs1458169230; called by mutect2, pindel, varscan2
- LZTS1 | c.1084A>T p.K362* | Nonsense Mutation (SNP) | VAF 25/94 reads (27%) | catalogued as COSV56118657; called by muse, mutect2, varscan2
- MEPE | c.1068C>A p.N356K | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV63073481; called by muse, mutect2, varscan2
- MGAT4C | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59829520, COSV59838193; called by muse, mutect2, varscan2
- MGAT5B | c.863T>C p.V288A | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV56937286; called by muse, mutect2, varscan2
- MOGAT2 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52221471; called by muse, mutect2, varscan2
- MPDZ | c.1946G>C p.C649S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV59951422, COSV59954495; called by muse, mutect2, varscan2
- MTPAP | c.870G>C p.E290D | Missense Mutation (SNP) | VAF 149/340 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV53936305; called by muse, mutect2, varscan2
- MYT1 | c.1226G>T p.G409V | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.49); PolyPhen benign (0.035); catalogued as COSV60514030; called by muse, mutect2, varscan2
- MYT1L | c.1801C>A p.R601S | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV67733244; called by muse, mutect2, varscan2
- NCKAP5 | c.4081C>G p.Q1361E | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV58476638; called by muse, mutect2, varscan2
- NDST4 | c.1902G>T p.Q634H | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV52138247; called by muse, mutect2, varscan2
- NES | c.4474A>T p.S1492C | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs777623798, COSV63963003; called by muse, mutect2, varscan2
- NLRP11 | c.2589G>T p.R863S | Missense Mutation (SNP) | VAF 102/225 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as COSV64088878; called by muse, mutect2, varscan2
- NLRP5 | c.3578A>G p.D1193G | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV66767562; called by muse, mutect2, varscan2
- NOS2 | c.383G>C p.G128A | Missense Mutation (SNP) | VAF 149/311 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.088); catalogued as COSV58227646; called by muse, mutect2, varscan2
- NPTX2 | c.823C>A p.Q275K | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1172767592, COSV55717923; called by muse, varscan2
- NR5A2 | c.298C>A p.L100I (on ENST00000367362 / NM_205860.3; = p.L54I on NM_003822.5) | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.66); catalogued as COSV52658238; called by muse, mutect2, varscan2
- NRXN1 | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV68008898, COSV68048920; called by muse, mutect2, varscan2
- NUP210 | c.1555G>T p.V519L | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV54414477; called by muse, mutect2, varscan2
- NYAP2 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1311059994, COSV56017053; called by muse, mutect2
- OBI1 | c.2123A>G p.K708R | Missense Mutation (SNP) | VAF 48/267 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV56147634; called by muse, mutect2, varscan2
- OBSL1 | c.1932G>T p.Q644H | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.908); catalogued as COSV54730114; called by muse, mutect2, varscan2
- OGFOD3 | c.699G>T p.K233N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57343505; called by muse, mutect2, varscan2
- OR2AG2 | c.109T>A p.L37M | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.937); catalogued as COSV58456319; called by muse, mutect2, varscan2
- OR4A15 | c.688G>T p.G230W | Missense Mutation (SNP) | VAF 98/208 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59034117, COSV59037860; called by muse, mutect2, varscan2
- OR51F1 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58580367; called by muse, mutect2, varscan2
- PALB2 | c.3096G>T p.M1032I | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV55170589; called by muse, mutect2, varscan2
- PCCA | c.1124G>C p.R375P | Missense Mutation (SNP) | VAF 50/275 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV66199176; called by muse, mutect2, varscan2
- PCDH17 | c.1301C>T p.T434I | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV64979588; called by muse, mutect2, varscan2
- PCDHB14 | c.279C>A p.D93E | Missense Mutation (SNP) | VAF 174/308 reads (56%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53391434; called by muse, mutect2, varscan2
- PCDHGB1 | c.2099T>A p.L700H | Missense Mutation (SNP) | VAF 163/267 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54038270; called by muse, mutect2, varscan2
- PCDHGC5 | c.804T>A p.D268E | Missense Mutation (SNP) | VAF 180/268 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52769176; called by muse, mutect2, varscan2
- PCMTD2 | c.946G>C p.E316Q | Missense Mutation (SNP) | VAF 96/195 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV55062888; called by muse, mutect2, varscan2
- PDE10A | c.823G>T p.V275F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV63106687; called by muse, mutect2, varscan2
- PIP | c.134C>A p.S45* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV99344273; called by muse, mutect2, varscan2
- PNLIPRP3 | c.215C>A p.A72E | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV65049760; called by muse, mutect2, varscan2
- PNPLA3 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as rs941771703, COSV53380582; called by muse, mutect2, varscan2
- PRDM8 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 65/220 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV60202869; called by muse, mutect2, varscan2
- PSG11 | c.868C>A p.Q290K | Missense Mutation (SNP) | VAF 72/356 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as COSV60453522, COSV60458007; called by muse, mutect2, varscan2
- PSPC1 | c.1183G>T p.D395Y | Missense Mutation (SNP) | VAF 124/190 reads (65%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.825); catalogued as COSV58891147; called by muse, varscan2
- PTCH2 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1490974921, COSV64709488; called by muse, mutect2, varscan2
- PTDSS1 | c.602T>A p.L201H | Missense Mutation (SNP) | VAF 60/332 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100428984; called by muse, mutect2, varscan2
- PTDSS1 | c.603C>A p.L201= | Splice Region (SNP) | VAF 63/332 reads (19%) | catalogued as COSV100428986; called by muse, mutect2, varscan2
- PTPRB | c.3450C>A p.Y1150* | Nonsense Mutation (SNP) | VAF 63/184 reads (34%) | catalogued as COSV54254165; called by muse, mutect2, varscan2
- PTPRS | c.2411C>G p.A804G | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.262); catalogued as COSV53638406, COSV99510644; called by muse, mutect2, varscan2
- PXDNL | c.1402C>T p.L468F | Missense Mutation (SNP) | VAF 33/268 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); catalogued as rs1388087139, COSV62488419; called by muse, mutect2, varscan2
- PYCR3 | c.734T>A p.L245H | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55309314; called by muse, mutect2, varscan2
- RASSF2 | c.653C>A p.A218E | Missense Mutation (SNP) | VAF 76/157 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV65083312; called by muse, mutect2, varscan2
- RBBP8NL | c.1951G>T p.D651Y | Missense Mutation (SNP) | VAF 78/172 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV53351209; called by muse, mutect2, varscan2
- RCOR3 | c.1075A>G p.T359A | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV65366014; called by muse, mutect2, varscan2
- RETSAT | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV55529090; called by muse, mutect2, varscan2
- RNMT | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as COSV51091505; called by muse, mutect2, varscan2
- RP1 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1229278794, COSV55127408, COSV99607660; called by muse, mutect2, varscan2
- RUNX1T1 | c.900C>A p.Y300* (on ENST00000265814 / NM_001198628.1; = p.Y273* on NM_004349.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 76/206 reads (37%) | catalogued as COSV56163887; called by muse, mutect2, varscan2
- SELE | c.1021T>A p.L341M | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV60977865; called by muse, mutect2, varscan2
- SEZ6L | c.2162C>A p.P721H | Missense Mutation (SNP) | VAF 75/125 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50661420; called by muse, mutect2, varscan2
- SLC22A5 | c.118G>C p.V40L | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV55371715, COSV55375130; called by muse, mutect2, varscan2
- SLC27A5 | c.1763C>A p.P588Q | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs1369710055, COSV54022170; called by muse, mutect2, varscan2
- SLC38A10 | c.1958C>T p.P653L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1237336257, COSV55849501; called by muse, mutect2, varscan2
- SLC6A15 | c.548C>A p.P183H | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57030097; called by muse, mutect2, varscan2
- SLC9C2 | c.2468G>T p.C823F | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV62949700; called by muse, mutect2, varscan2
- SNIP1 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.034); catalogued as rs1050240331, COSV56166213; called by muse, mutect2
- SNTG1 | c.810+2T>A p.X270_splice | Splice Site (SNP) | VAF 32/80 reads (40%) | catalogued as COSV52474407; called by muse, mutect2, varscan2
- SORT1 | c.1703A>G p.Y568C | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.695); catalogued as COSV56670324; called by muse, mutect2, varscan2
- SPON1 | c.425G>C p.R142P | Missense Mutation (SNP) | VAF 100/237 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100116711; called by muse, mutect2, varscan2
- SUCLG1 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV67265975; called by muse, mutect2, varscan2
- SULT1B1 | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60209570; called by muse, mutect2, varscan2
- SUMF1 | c.660G>T p.W220C | Missense Mutation (SNP) | VAF 113/186 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55996190; called by muse, mutect2, varscan2
- TIAM1 | c.3030T>G p.H1010Q | Missense Mutation (SNP) | VAF 85/154 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.203); catalogued as COSV54575761; called by muse, mutect2, varscan2
- TIGD7 | c.1025A>G p.Y342C | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51917084; called by muse, mutect2, varscan2
- TNS1 | c.1337G>T p.G446V | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50772728; called by muse, mutect2, varscan2
- TRIM17 | c.306C>A p.H102Q | Missense Mutation (SNP) | VAF 84/199 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1558459321, COSV54384454; called by muse, mutect2, varscan2
- TRPC4 | c.1189C>A p.P397T | Missense Mutation (SNP) | VAF 102/154 reads (66%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV59020104; called by muse, mutect2, varscan2
- TTLL4 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 38/319 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.058); catalogued as COSV51439677; called by muse, mutect2, varscan2
- TUBGCP4 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329116285, COSV53021641; called by muse, mutect2, varscan2
- UCHL5 | c.973G>T p.A325S | Missense Mutation (SNP) | VAF 93/386 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as COSV66487233; called by muse, mutect2, varscan2
- UGT2B7 | c.8T>C p.V3A | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.138); catalogued as COSV59445580; called by muse, mutect2, varscan2
- USH2A | c.6767C>A p.S2256Y | Missense Mutation (SNP) | VAF 343/741 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56440961; called by muse, mutect2, varscan2
- USH2A | c.1172G>T p.S391I | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs949082769, CM044729, COSV100228401, COSV56440984; called by muse, mutect2, varscan2
- ZBTB10 | c.716C>A p.P239H | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as rs750614916, COSV66948631; called by muse, mutect2, varscan2
- ZFAT | c.1316A>T p.H439L | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64747640; called by muse, mutect2, varscan2
- ZFHX4 | c.9734C>A p.A3245E | Missense Mutation (SNP) | VAF 127/356 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51497495; called by muse, mutect2, varscan2
- ZNF678 | c.76G>T p.V26F | Missense Mutation (SNP) | VAF 140/437 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.403); catalogued as COSV59381488; called by muse, mutect2, varscan2
- ZNF831 | c.2365G>T p.A789S | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.85); PolyPhen benign (0.006); catalogued as COSV64045550; called by muse, mutect2, varscan2
- ATP9B | c.2298_2308del p.G767Rfs*15 | Frame Shift Del (DEL) | VAF 21/133 reads (16%) | called by mutect2, pindel, varscan2
- CBWD3 | c.908T>A p.V303E | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.351); called by mutect2, varscan2
- CERS3 | c.693del p.T232Pfs*3 | Frame Shift Del (DEL) | VAF 21/141 reads (15%) | called by mutect2, pindel, varscan2
- EYA2 | c.1289dup p.A431Gfs*40 | Frame Shift Ins (INS) | VAF 41/111 reads (37%) | called by mutect2, pindel, varscan2
- MPP3 | c.460del p.D154Tfs*33 | Frame Shift Del (DEL) | VAF 33/184 reads (18%) | called by mutect2, pindel, varscan2
- POLR2A | c.2873G>C p.R958P | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- PPFIBP2 | c.1290_1295del p.G431_A432del | In Frame Del (DEL) | VAF 58/279 reads (21%) | called by mutect2, pindel, varscan2
- RICTOR | c.2150_2154del p.L717Qfs*8 | Frame Shift Del (DEL) | VAF 16/118 reads (14%) | called by mutect2, pindel, varscan2
- SPRED2 | c.964del p.R322Afs*12 | Frame Shift Del (DEL) | VAF 76/339 reads (22%) | called by mutect2, pindel, varscan2
- YTHDC1 | c.926dup p.I310Nfs*4 | Frame Shift Ins (INS) | VAF 69/323 reads (21%) | called by mutect2, pindel, varscan2
- AADAT | c.510C>T p.S170= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as rs758776795, COSV61787550; called by muse, mutect2, varscan2
- AFM | c.927G>A p.E309= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as rs1245228309, COSV56921752, COSV56922298; called by muse, mutect2, varscan2
- AHCYL2 | c.936G>C p.G312= | Silent (SNP) | VAF 99/226 reads (44%) | catalogued as rs751323577, COSV61491422; called by muse, mutect2, varscan2
- BLM | c.3282A>G p.S1094= | Silent (SNP) | VAF 65/146 reads (45%) | catalogued as COSV61927650; called by muse, mutect2, varscan2
- BNC2 | c.270A>T p.P90= | Silent (SNP) | VAF 69/266 reads (26%) | catalogued as COSV66157957; called by muse, mutect2, varscan2
- BOLL | c.72C>T p.A24= | Silent (SNP) | VAF 84/300 reads (28%) | catalogued as COSV56577684; called by muse, varscan2
- BPIFB4 | c.1443C>A p.I481= | Silent (SNP) | VAF 99/230 reads (43%) | catalogued as COSV64952321; called by muse, mutect2, varscan2
- CCSER1 | c.1890A>T p.A630= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as COSV61471374; called by muse, mutect2, varscan2
- CDC14A | c.717C>T p.D239= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as rs765677912, COSV60563816; called by muse, mutect2, varscan2
- CDH22 | c.408G>T p.R136= | Silent (SNP) | VAF 27/134 reads (20%) | catalogued as COSV64839757; called by muse, mutect2, varscan2
- CES5A | c.516C>A p.V172= | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as COSV51865094, COSV51870943; called by muse, mutect2, varscan2
- COL12A1 | c.8313G>C p.G2771= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100486540, COSV59408550; called by muse, mutect2, varscan2
- CPNE6 | c.1477C>A p.R493= | Silent (SNP) | VAF 63/97 reads (65%) | catalogued as COSV53746660, COSV99393962; called by muse, mutect2, varscan2
- CPQ | c.201G>A p.L67= | Silent (SNP) | VAF 51/155 reads (33%) | catalogued as COSV99615110; called by muse, mutect2, varscan2
- CPXM2 | c.1443T>C p.I481= | Silent (SNP) | VAF 65/179 reads (36%) | catalogued as COSV53871480; called by muse, mutect2, varscan2
- CRISP2 | c.315T>A p.T105= | Silent (SNP) | VAF 25/134 reads (19%) | catalogued as COSV59257010; called by muse, mutect2, varscan2
- CUBN | c.5982G>T p.P1994= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as COSV64716353, COSV64727785; called by muse, mutect2, varscan2
- DCTN4 | c.13C>T p.L5= | Silent (SNP) | VAF 76/132 reads (58%) | catalogued as rs1215100059, COSV69783113; called by muse, mutect2, varscan2
- ECM2 | c.168G>A p.Q56= | Silent (SNP) | VAF 80/165 reads (48%) | catalogued as rs760253173, COSV60740521; called by muse, mutect2, varscan2
- EHMT2 | c.2421G>A p.R807= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as COSV64998138; called by muse, mutect2, varscan2
- FAM71B | c.1737T>C p.G579= | Silent (SNP) | VAF 240/410 reads (59%) | catalogued as COSV57231430; called by muse, mutect2, varscan2
- GAD2 | c.1392T>A p.T464= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV52168757; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1920C>T p.P640= | Silent (SNP) | VAF 17/179 reads (9%) | catalogued as rs782719821, COSV56086171; called by muse, mutect2
- IGLV2-14 | c.66C>A p.A22= | Silent (SNP) | VAF 181/338 reads (54%) | called by muse, mutect2, varscan2
- IGSF10 | c.3351C>T p.P1117= | Silent (SNP) | VAF 133/225 reads (59%) | catalogued as COSV56792094; called by muse, mutect2, varscan2
- IL17RD | c.2202C>T p.H734= | Silent (SNP) | VAF 121/192 reads (63%) | catalogued as rs1242465048, COSV56343214; called by muse, mutect2, varscan2
- INSC | c.7C>A p.R3= | Silent (SNP) | VAF 45/101 reads (45%) | catalogued as COSV65411409, COSV65413314; called by muse, mutect2, varscan2
- KCTD2 | c.568C>T p.L190= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs755797949, COSV59369704; called by muse, mutect2, varscan2
- KIF19 | c.1743G>C p.S581= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV63430683; called by muse, mutect2, varscan2
- KLK3 | c.240G>T p.L80= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV58100668, COSV58103106; called by muse, mutect2, varscan2
- LPA | c.4092G>T p.V1364= | Silent (SNP) | VAF 36/150 reads (24%) | catalogued as rs376480107; called by muse, mutect2, varscan2
- LRRC66 | c.1821G>T p.G607= | Silent (SNP) | VAF 33/210 reads (16%) | catalogued as COSV58632065, COSV58636956; called by muse, mutect2, varscan2
- LZTS2 | c.579C>G p.S193= | Silent (SNP) | VAF 87/498 reads (17%) | catalogued as COSV64652982; called by muse, mutect2, varscan2
- MDFI | c.621C>A p.G207= | Silent (SNP) | VAF 45/193 reads (23%) | catalogued as COSV57822947; called by muse, mutect2, varscan2
- N4BP2 | c.2970A>G p.V990= | Silent (SNP) | VAF 28/145 reads (19%) | catalogued as COSV54707210; called by muse, mutect2, varscan2
- NEB | c.10746G>T p.V3582= | Silent (SNP) | VAF 302/669 reads (45%) | catalogued as COSV51461753; called by muse, mutect2, varscan2
- NLRC5 | c.4899G>T p.L1633= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as COSV52663536; called by muse, mutect2, varscan2
- NR1H4 | c.369C>A p.R123= (on ENST00000551379 / NM_001206993.2; = p.R113= on NM_005123.4) | Silent (SNP) | VAF 58/187 reads (31%) | catalogued as COSV51857080, COSV99500350; called by muse, mutect2, varscan2
- OR10G4 | c.387C>A p.L129= | Silent (SNP) | VAF 66/408 reads (16%) | catalogued as COSV57979096; called by muse, varscan2
- OR10G7 | c.918A>G p.V306= | Silent (SNP) | VAF 40/91 reads (44%) | catalogued as COSV57868960; called by muse, mutect2, varscan2
- OR10Q1 | c.192T>C p.Y64= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as COSV57472091, COSV57472192; called by muse, mutect2, varscan2
- OR13C8 | c.312T>A p.S104= | Silent (SNP) | VAF 98/158 reads (62%) | catalogued as rs774500176, COSV58612532; called by muse, mutect2, varscan2
- OR13G1 | c.135C>T p.A45= | Silent (SNP) | VAF 43/97 reads (44%) | catalogued as COSV62945336; called by muse, mutect2, varscan2
- OR2T11 | c.235C>T p.L79= | Silent (SNP) | VAF 49/85 reads (58%) | catalogued as COSV58186710, COSV58187385; called by muse, mutect2, varscan2
- OR2T12 | c.501C>T p.C167= | Silent (SNP) | VAF 80/219 reads (37%) | catalogued as rs144239623; called by muse, mutect2, varscan2
- OR3A3 | c.117C>T p.L39= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV99351579; called by muse, mutect2, varscan2
- OR6C1 | c.513T>A p.I171= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as COSV65574546; called by muse, mutect2, varscan2
- OSBPL1A | c.2472A>G p.V824= (on ENST00000319481 / NM_080597.4; = p.V311= on NM_018030.4) | Silent (SNP) | VAF 50/157 reads (32%) | catalogued as rs1476385148, COSV60204539; called by muse, mutect2, varscan2
- PCDHA8 | c.1629G>T p.P543= | Silent (SNP) | VAF 131/183 reads (72%) | catalogued as COSV65333069, COSV65333143; called by muse, mutect2, varscan2
- PHF21B | c.375G>A p.A125= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as rs560827322, COSV57558750; called by muse, mutect2, varscan2
- PIGO | c.72C>T p.F24= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV53055542; called by muse, mutect2, varscan2
- PIP | c.135A>G p.S45= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV99344275; called by muse, mutect2, varscan2
- PSG2 | c.456C>T p.S152= | Silent (SNP) | VAF 94/487 reads (19%) | catalogued as COSV61546617; called by muse, varscan2
- PTPRH | c.3177G>T p.R1059= | Silent (SNP) | VAF 75/181 reads (41%) | catalogued as COSV99671488; called by muse, mutect2, varscan2
- PTPRT | c.3567G>T p.V1189= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as COSV62023727; called by muse, mutect2, varscan2
- RTL3 | c.780T>C p.S260= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV58186013; called by muse, mutect2
- SCN3A | c.3654C>A p.L1218= | Silent (SNP) | VAF 24/197 reads (12%) | catalogued as COSV51825260; called by muse, mutect2, varscan2
- SCN3A | c.2532G>T p.V844= | Silent (SNP) | VAF 65/248 reads (26%) | catalogued as COSV51825274; called by muse, mutect2, varscan2
- SLC39A11 | c.213G>T p.G71= | Silent (SNP) | VAF 50/106 reads (47%) | catalogued as COSV55303019; called by muse, mutect2, varscan2
- SLC5A5 | c.1701C>A p.L567= | Silent (SNP) | VAF 141/208 reads (68%) | catalogued as COSV55835703; called by muse, mutect2, varscan2
- SNAP91 | c.2535T>A p.A845= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV52135123; called by muse, mutect2, varscan2
- SPDEF | c.981C>T p.L327= | Silent (SNP) | VAF 42/201 reads (21%) | catalogued as rs942657181, COSV55062591; called by muse, mutect2, varscan2
- SPON1 | c.426G>C p.R142= | Silent (SNP) | VAF 98/233 reads (42%) | catalogued as rs782353582, COSV100116714; called by muse, mutect2, varscan2
- STAB2 | c.5706T>C p.C1902= | Silent (SNP) | VAF 17/140 reads (12%) | catalogued as rs1357424670, COSV66347553; called by muse, mutect2, varscan2
- SYN3 | c.1587A>T p.P529= | Silent (SNP) | VAF 78/135 reads (58%) | catalogued as COSV60516890; called by muse, mutect2, varscan2
- TOX2 | c.372C>A p.L124= (on ENST00000358131 / NM_001098798.2; = p.L73= on NM_032883.3) | Silent (SNP) | VAF 36/61 reads (59%) | catalogued as COSV57892932, COSV57896085; called by muse, mutect2, varscan2
- TRIM11 | c.1269G>T p.G423= | Silent (SNP) | VAF 59/132 reads (45%) | catalogued as COSV52860304; called by muse, mutect2, varscan2
- TRIML1 | c.96G>T p.G32= | Silent (SNP) | VAF 74/295 reads (25%) | catalogued as COSV60196528, COSV60196992; called by muse, mutect2, varscan2
- ULK4 | c.48T>A p.T16= | Silent (SNP) | VAF 77/129 reads (60%) | catalogued as COSV57224211; called by muse, mutect2, varscan2
- ZNF831 | c.2247C>A p.V749= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs767005659, COSV64045548; called by muse, mutect2, varscan2
- SSPOP | n.8769G>T | RNA (SNP) | VAF 23/80 reads (29%) | catalogued as COSV65137724; called by muse, mutect2, varscan2
- USP29 | c.-2G>C | 5'UTR (SNP) | VAF 7/64 reads (11%) | catalogued as COSV99572534; called by muse, mutect2
- USP29 | c.-1G>T | 5'UTR (SNP) | VAF 7/63 reads (11%) | catalogued as COSV99572537; called by muse, mutect2
